Somatic mutation profile of tumor specimen CPT008917 (aliquot CPT008917-0002) from CPTAC case 09BR001, project CPTAC-2 (Breast). Tissue or organ of origin: Breast, NOS.
Specimen CPT008917: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccc00309-4ce5-4c3d-88e6-47b35a76e699.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT008545 (Blood Derived Normal), aliquot CPT008545-0001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c01de9c5-4f3c-4b30-ae1d-fb76a971d445

The open-access MAF lists 43 somatic variants for this specimen: 29 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 11, Nonsense Mutation 2, 5'UTR 1, RNA 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 119/285 reads (42%) | catalogued as rs1555484797, COSV52120614; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.4102C>T p.R1368C | Missense Mutation (SNP) | VAF 50/694 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1183074086, CM129560; called by muse, mutect2
- CDH1 | c.2017C>T p.Q673* | Nonsense Mutation (SNP) | VAF 87/180 reads (48%) | catalogued as COSV55729046; called by muse, mutect2, varscan2
- CROCC2 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs922598829; called by muse, mutect2, varscan2
- DCDC1 | c.4156C>T p.R1386C (on ENST00000597505 / NM_001367979.1; = p.R493C on NM_020869.3) | Missense Mutation (SNP) | VAF 57/397 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.555); catalogued as rs201587746, COSV58000770; called by muse, mutect2, varscan2
- FBXL18 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs778622022, COSV101212040, COSV66667698; called by muse, mutect2, varscan2
- FOXA1 | c.762C>A p.F254L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51648762; called by muse, varscan2
- GLT6D1 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs200843676, COSV65628200; called by muse, mutect2, varscan2
- INSRR | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 79/756 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs143369504; called by muse, mutect2, varscan2
- NEB | c.5054C>T p.T1685I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200050128; called by muse, mutect2, varscan2
- POLR1A | c.302G>C p.R101P | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99808408, COSV99808621; called by muse, mutect2, varscan2
- SLIT3 | c.4321G>A p.E1441K | Missense Mutation (SNP) | VAF 46/444 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.311); catalogued as rs180813266; called by muse, mutect2
- SPHK1 | c.1042G>A p.E348K (on ENST00000392496 / NM_001355139.2; = p.E362K on NM_021972.4) | Missense Mutation (SNP) | VAF 122/809 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.158); catalogued as rs143355437; called by muse, mutect2, varscan2
- ZNF517 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 71/424 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs866431601, COSV63464852; called by mutect2, varscan2
- CAP2 | c.283T>C p.Y95H | Missense Mutation (SNP) | VAF 70/124 reads (56%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCL11 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 73/273 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRND | c.203A>G p.E68G | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNM1 | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FBN3 | c.2375G>A p.G792D | Missense Mutation (SNP) | VAF 31/347 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2
- HS6ST3 | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 56/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRAG1 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- MAP2K4 | c.989_1009del p.N330_S337delinsT | In Frame Del (DEL) | VAF 34/97 reads (35%) | called by mutect2, pindel, varscan2
- MTPAP | c.1617G>T p.K539N | Missense Mutation (SNP) | VAF 92/360 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH7B | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP2R3A | c.1513A>G p.S505G | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2
- PTPRO | c.611C>A p.T204N | Missense Mutation (SNP) | VAF 89/304 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- TULP3 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- ZNF444 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZPBP2 | c.487T>G p.F163V (on ENST00000348931 / NM_199321.3; = p.F141V on NM_198844.3) | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- CASQ1 | c.225C>T p.P75= | Silent (SNP) | VAF 200/461 reads (43%) | catalogued as rs374653743, COSV100927299; called by muse, mutect2, varscan2
- CBLN3 | c.312C>T p.N104= | Silent (SNP) | VAF 34/213 reads (16%) | catalogued as rs768319001; called by muse, mutect2, varscan2
- CD40 | c.474C>T p.F158= | Silent (SNP) | VAF 66/1091 reads (6%) | catalogued as rs79661585; ClinVar: likely benign; called by muse, mutect2
- CDX4 | c.201G>A p.P67= | Silent (SNP) | VAF 56/259 reads (22%) | called by muse, mutect2, varscan2
- CHD5 | c.4512C>T p.I1504= | Silent (SNP) | VAF 150/302 reads (50%) | catalogued as rs780638490; called by mutect2, varscan2
- CHST3 | c.1113C>T p.Y371= | Silent (SNP) | VAF 57/337 reads (17%) | called by muse, mutect2, varscan2
- CYP2W1 | c.540C>T p.F180= | Silent (SNP) | VAF 182/447 reads (41%) | catalogued as rs529400808, COSV100417126; called by muse, mutect2, varscan2
- FADS6 | c.219G>A p.A73= | Silent (SNP) | VAF 62/820 reads (8%) | called by muse, mutect2
- SDK2 | c.3810G>A p.V1270= | Silent (SNP) | VAF 99/286 reads (35%) | called by muse, mutect2, varscan2
- ZFP42 | c.558C>T p.S186= | Silent (SNP) | VAF 49/234 reads (21%) | catalogued as rs1310690864, COSV100479209, COSV58819423; called by muse, mutect2, varscan2
- ZNF444 | c.27G>A p.Q9= | Silent (SNP) | VAF 9/35 reads (26%) | called by mutect2, varscan2
- ANKRD54 | chr22:37847678 C>T | 5'Flank (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- FMN2 | c.-31C>T | 5'UTR (SNP) | VAF 20/165 reads (12%) | called by muse, mutect2, varscan2
- RPL26P30 | n.836C>T | RNA (SNP) | VAF 68/480 reads (14%) | catalogued as rs772398101; called by muse, mutect2, varscan2
